Somatic mutation profile of tumor specimen 256ac9f5-1e19-44b4-92fb-fef3fc (aliquot 256ac9f5-1e19-44b4-92fb-fef3fc_D6) from CPTAC case 01OV049, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 256ac9f5-1e19-44b4-92fb-fef3fc: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbaf63ce-a09f-418d-bf94-dcc96cc1f9f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen d7a7b9e7-3121-404f-9fd4-22673a (Blood Derived Normal), aliquot d7a7b9e7-3121-404f-9fd4-22673a_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41cf8823-6b8e-4768-9a1f-eba6ea491969

The open-access MAF lists 45 somatic variants for this specimen: 31 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 11, Nonsense Mutation 2, 5'Flank 1, 5'UTR 1, Nonstop Mutation 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 165/251 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAT1 | c.914A>G p.N305S | Missense Mutation (SNP) | VAF 67/281 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs562043215; called by muse, mutect2, varscan2
- CDKN2B | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 193/731 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as rs753878524, COSV52805695; called by muse, mutect2, varscan2
- CNTNAP5 | c.3530A>C p.K1177T | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV70471425; called by muse, mutect2, varscan2
- DUOX2 | c.2296C>A p.R766S | Missense Mutation (SNP) | VAF 271/479 reads (57%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as rs746012866; called by muse, mutect2, varscan2
- LEMD3 | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 102/253 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.043); catalogued as rs374194981; called by muse, mutect2, varscan2
- MC5R | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 94/272 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1485593304, COSV61253907; called by muse, mutect2, varscan2
- NRDE2 | c.3212G>A p.R1071Q | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761336895; called by muse, mutect2, varscan2
- PAPPA2 | c.1863G>C p.W621C | Missense Mutation (SNP) | VAF 244/311 reads (78%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.912); catalogued as COSV62781709; called by muse, mutect2, varscan2
- PSMD14 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.22); catalogued as COSV101293957; called by muse, mutect2, varscan2
- SNX10 | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1048719660, COSV58401958; called by muse, mutect2
- XIRP2 | c.8917G>C p.D2973H (on ENST00000628543; = p.D3148H on NM_152381.6) | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV54729691; called by muse, mutect2
- ZNF106 | c.3995A>G p.Q1332R | Missense Mutation (SNP) | VAF 65/242 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs987877178; called by muse, mutect2, varscan2
- CCDC142 | c.2162A>G p.N721S (on ENST00000393965 / NM_001365575.2; = p.N714S on NM_032779.4) | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.827); called by muse, mutect2
- CCDC148 | c.688A>C p.S230R | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CD8B | c.224C>A p.S75Y | Missense Mutation (SNP) | VAF 16/334 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.46); called by muse, mutect2
- CDHR2 | c.83C>G p.A28G | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTN5 | c.1777T>A p.C593S | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSHL1 | c.319C>T p.L107F (on ENST00000309894 / NM_022581.3; = p.L13F on NM_001318.4) | Missense Mutation (SNP) | VAF 242/297 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD1 | c.8510C>A p.S2837Y (on ENST00000520002; = p.S2836Y on NM_033225.6) | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FCGBP | c.5819G>A p.W1940* | Nonsense Mutation (SNP) | VAF 83/499 reads (17%) | called by muse, mutect2, varscan2
- IFIH1 | c.65T>G p.V22G | Missense Mutation (SNP) | VAF 133/542 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- KMT5B | c.545T>G p.V182G | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); called by muse, mutect2
- MANSC1 | c.1294T>A p.*432Kext*25 | Nonstop Mutation (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2
- MBTPS1 | c.1594-1G>T p.X532_splice | Splice Site (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- MUC17 | c.12250G>C p.V4084L | Missense Mutation (SNP) | VAF 118/220 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOLC1 | c.11C>G p.A4G | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- PER1 | c.1013T>A p.L338Q | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RPGRIP1 | c.1461G>C p.Q487H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- TSGA10 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 32/95 reads (34%) | called by muse, mutect2, varscan2
- ZNF804A | c.3578C>T p.P1193L | Missense Mutation (SNP) | VAF 116/229 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ACTR2 | c.366G>A p.K122= | Silent (SNP) | VAF 23/143 reads (16%) | catalogued as rs1268623003; called by muse, mutect2, varscan2
- ALDOC | c.729G>A p.K243= | Silent (SNP) | VAF 96/140 reads (69%) | called by muse, mutect2, varscan2
- CASZ1 | c.1782C>T p.D594= | Silent (SNP) | VAF 359/536 reads (67%) | called by muse, mutect2, varscan2
- CCDC168 | c.60A>G p.T20= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as rs191737990; called by muse, mutect2, varscan2
- DUS1L | c.213C>G p.P71= | Silent (SNP) | VAF 115/233 reads (49%) | catalogued as COSV60785408; called by muse, mutect2, varscan2
- FSIP2 | c.14052G>T p.L4684= | Silent (SNP) | VAF 104/245 reads (42%) | catalogued as COSV100555248; called by muse, mutect2, varscan2
- INTS4 | c.234A>G p.E78= | Silent (SNP) | VAF 29/100 reads (29%) | called by muse, mutect2, varscan2
- MUC12 | c.15879G>A p.S5293= (on ENST00000379442; = p.S5150= on NM_001164462.1) | Silent (SNP) | VAF 81/353 reads (23%) | catalogued as rs1007108146; called by muse, mutect2, varscan2
- MYH7 | c.4944C>T p.S1648= | Silent (SNP) | VAF 117/456 reads (26%) | called by muse, mutect2, varscan2
- TTC6 | c.249G>A p.A83= | Silent (SNP) | VAF 66/236 reads (28%) | catalogued as COSV101606805; called by muse, mutect2, varscan2
- TTN | c.58404T>C p.D19468= (on ENST00000591111; = p.D12044= on NM_003319.4) | Silent (SNP) | VAF 49/172 reads (28%) | called by muse, mutect2, varscan2
- FAM53C | chr5:138338125 G>C | 5'Flank (SNP) | VAF 71/202 reads (35%) | called by muse, mutect2, varscan2
- TMTC4 | c.163-1664G>A | Intron (SNP) | VAF 41/203 reads (20%) | catalogued as rs1258366253; called by muse, mutect2, varscan2
- ZNF117 | c.-16A>G | 5'UTR (SNP) | VAF 8/50 reads (16%) | catalogued as rs1223078098; called by muse, mutect2, varscan2
